FM case AD9361 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/4ba0d2b0-160a-47a8-bd66-0c4f66df3637

Male, 68.9 years: Mucinous carcinoma (ICD-O-3 8480/3) of the appendix; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
